Surgical pathology report (de-identified scan), TCGA case TCGA-61-1995, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1995-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY –

- A. HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA INVOLVING RIGHT OVARY AND RIGHT FALLOPIAN TUBE.
- B. FOCAL LYMPHOVASCULAR INVASION IDENTIFIED.
- C. PELVIC CYTOLOGY [REDACTED] IS POSITIVE MALIGNANT CELLS.
- D. FIGO TUMOR STAGE: IV.

PART 2: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY –

- A. HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA INVOLVING LEFT OVARY.
- B. LEFT FALLOPIAN TUBE, UNREMARKABLE.

PART 3: UTERUS, WITHOUT ADNEXA (162 GRAMS) AND ANTERIOR BLADDER PERITONEUM, TOTAL ABDOMINAL HYSTERECTOMY AND EXCISION –

- A. METASTATIC HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA INVOLVING ANTERIOR BLADDER PERITONEUM, UTERINE SEROSA AND ADJACENT MYOMETRIUM.
- B. CERVIX WITH LYMPHOVASCULAR INVASION BY METASTATIC HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.
- C. WEAKLY PROLIFERATING ENDOMETRIUM.
- D. ADENOMYOSIS.

PART 4: SIGMOID MESENTERY NODULE, EXCISION –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

PART 5: RIGHT PELVIC PERITONEUM, EXCISION –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

PART 6: RIGHT PERICOLIC GUTTER TUMOR, EXCISION –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

PART 7: APPENDIX, APPENDECTOMY –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA INVOLVING APPENDICEAL SEROSA AND PERIAPPENDICEAL TISSUE.

PART 8: PERIAORTIC LYMPH NODES, DISSECTION –

TWO LYMPH NODES POSITIVE FOR HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA (2/2).

PART 9: OMENTUM, OMENTECTOMY –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

PART 10: DIAPHRAGMATIC NODULE, EXCISION –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

PART 11: MESENTERIC NODULE, EXCISION –

HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA.

[page 2 of 2]
SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 17.5 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
HISTOLOGIC GRADE (serous tumors):	High grade
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 2
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 2 Number of positive lymph nodes, Left: 0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	T STAGE, PATHOLOGIC** continued on next page T STAGE, PATHOLOGIC** continued
N STAGE, PATHOLOGIC:	pT3c
M STAGE, PATHOLOGIC:	pN1
FIGO STAGE:	pM1 IV

Source: NCI Genomic Data Commons file ab7768ef-4a5a-4b45-a594-febe572c29bc (TCGA-61-1995.5EA6D43B-376D-43CB-873F-C33EC814A95D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).